Somatic mutation profile of tumor specimen MMRF_1361_1_BM_CD138pos (aliquot MMRF_1361_1_BM_CD138pos_T1_KAS5U_L01939) from MMRF case MMRF_1361, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 67.4 years (24,610 days).
Specimen MMRF_1361_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6eaf8a52-af09-4fea-b970-34b06c1ceb45.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1361_2_PB_CD3pos (Blood Derived Normal), aliquot MMRF_1361_2_PB_CD3pos_C1_KAS5U_L01930; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/82a1f775-b789-484b-8bff-99fd1bc85d23

The open-access MAF lists 79 somatic variants for this specimen: 28 protein-altering or splice-affecting, 4 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 24, Missense Mutation 22, Intron 15, Silent 4, RNA 4, Frame Shift Del 3, 3'Flank 2, 5'Flank 1, In Frame Del 1, Splice Region 1, Nonsense Mutation 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.176C>A p.A59E | Missense Mutation (SNP) | VAF 45/89 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV55568979, COSV55604554, COSV55904854; called by muse, mutect2, varscan2
- BMI1 | c.317-3T>C | Splice Region (SNP) | VAF 43/83 reads (52%) | catalogued as rs1422079023, COSV64959144; called by muse, mutect2, varscan2
- CXorf58 | c.740C>T p.T247M | Missense Mutation (SNP) | VAF 112/130 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs761720174, COSV64858330; called by muse, mutect2, varscan2
- FAM47B | c.533A>C p.E178A | Missense Mutation (SNP) | VAF 64/65 reads (98%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV100264658; called by muse, mutect2, varscan2
- GPR152 | c.98C>T p.T33M | Missense Mutation (SNP) | VAF 60/103 reads (58%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs778997675, COSV56885395; called by muse, mutect2, varscan2
- HK2 | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 8/237 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as COSV99308935; called by muse, mutect2
- IGLV3-25 | c.66G>C p.E22D | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.03); catalogued as rs376421895; called by muse, mutect2, varscan2
- NAALADL2 | c.2206C>A p.L736I | Missense Mutation (SNP) | VAF 113/230 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.056); catalogued as rs1322082924; called by muse, mutect2, varscan2
- PHF20 | c.2258T>C p.I753T | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.644); catalogued as rs376078655; called by muse, mutect2, varscan2
- PHRF1 | c.2509G>A p.G837S (on ENST00000264555 / NM_001286581.2; = p.G836S on NM_020901.4) | Missense Mutation (SNP) | VAF 109/204 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs199793786; called by muse, mutect2, varscan2
- PKHD1 | c.4601G>C p.S1534T | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.03); catalogued as COSV100584911, COSV61895893; called by muse, varscan2
- SI | c.4155G>T p.K1385N | Missense Mutation (SNP) | VAF 87/176 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.102); catalogued as rs760213744; called by muse, mutect2, varscan2
- ASB2 | c.76C>T p.P26S | Missense Mutation (SNP) | VAF 71/72 reads (99%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ASXL1 | c.1933G>A p.G645S | Missense Mutation (SNP) | VAF 37/96 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BOD1L1 | c.3472A>G p.T1158A | Missense Mutation (SNP) | VAF 5/88 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.005); called by muse, mutect2
- BTBD8 | c.1801del p.T601Lfs*2 (on ENST00000636805 / NM_001376131.1; = p.T88Lfs*2 on NM_015237.4) | Frame Shift Del (DEL) | VAF 34/83 reads (41%) | called by mutect2, pindel, varscan2
- CD2AP | c.1683del p.A562Lfs*3 | Frame Shift Del (DEL) | VAF 40/89 reads (45%) | called by pindel, varscan2
- CIP2A | c.103G>C p.V35L | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.29); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ESR2 | c.845T>C p.I282T | Missense Mutation (SNP) | VAF 52/52 reads (100%) | SIFT tolerated (0.3); PolyPhen benign (0.121); called by muse, mutect2, varscan2
- GPR19 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 129/260 reads (50%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2, varscan2
- NLRP13 | c.2265del p.C755* | Frame Shift Del (DEL) | VAF 37/91 reads (41%) | called by mutect2, pindel, varscan2
- RYR2 | c.4216A>C p.T1406P | Missense Mutation (SNP) | VAF 132/545 reads (24%) | SIFT tolerated (0.35); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- SLC12A7 | c.2833G>A p.E945K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.185); called by muse, mutect2, varscan2
- SLC5A12 | c.1629T>A p.C543* | Nonsense Mutation (SNP) | VAF 80/155 reads (52%) | called by muse, mutect2, varscan2
- TASOR | c.4775C>T p.P1592L (on ENST00000355628 / NM_001365636.2; = p.P1216L on NM_015224.3) | Missense Mutation (SNP) | VAF 224/506 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); called by muse, mutect2, varscan2
- TEX15 | c.6751_6753del p.I2251del (on ENST00000256246; = p.I2634del on NM_001350162.2) | In Frame Del (DEL) | VAF 50/92 reads (54%) | called by mutect2, pindel, varscan2
- TOP2B | c.424A>T p.N142Y (on ENST00000264331 / NM_001330700.2; = p.N137Y on NM_001068.3) | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFHX4 | c.4549C>A p.P1517T | Missense Mutation (SNP) | VAF 11/236 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.91); called by muse, mutect2
- EGR1 | c.102G>A p.K34= | Silent (SNP) | VAF 78/166 reads (47%) | catalogued as rs368477832, COSV53518271; called by muse, varscan2
- IGHV2-70 | c.30A>C p.L10= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs781292434; called by mutect2, varscan2
- ITGA9 | c.2712C>T p.N904= | Silent (SNP) | VAF 80/158 reads (51%) | called by muse, mutect2, varscan2
- MAP4K4 | c.1140G>A p.Q380= | Silent (SNP) | VAF 40/89 reads (45%) | called by muse, mutect2, varscan2
- AC134312.1 | n.234C>T | RNA (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- ACADSB | c.*1932T>A | 3'UTR (SNP) | VAF 24/45 reads (53%) | called by muse, varscan2
- ACTR8 | c.*1358G>T | 3'UTR (SNP) | VAF 43/114 reads (38%) | called by muse, mutect2, varscan2
- AGBL3 | c.*291T>A | 3'UTR (SNP) | VAF 82/156 reads (53%) | called by muse, mutect2, varscan2
- AKAP13 | c.478+155C>T | Intron (SNP) | VAF 10/21 reads (48%) | catalogued as rs1567110727; called by muse, mutect2, varscan2
- AP001360.3 | n.464C>T | RNA (SNP) | VAF 17/35 reads (49%) | catalogued as rs954734307; called by muse, mutect2, varscan2
- APOOL | c.*60G>T | 3'UTR (SNP) | VAF 108/128 reads (84%) | called by muse, mutect2, varscan2
- ARC | c.*437C>T | 3'UTR (SNP) | VAF 31/49 reads (63%) | catalogued as rs1450243979; called by muse, mutect2, varscan2
- ASGR1 | c.*51C>T | 3'UTR (SNP) | VAF 61/102 reads (60%) | catalogued as rs548074236, COSV99352385; called by muse, mutect2, varscan2
- ASH1L | c.5828+4799G>A | Intron (SNP) | VAF 12/59 reads (20%) | catalogued as rs771331473; called by mutect2, varscan2
- BMP6 | c.*977C>T | 3'UTR (SNP) | VAF 18/120 reads (15%) | called by mutect2, varscan2
- BORCS7 | c.*1493G>C | 3'UTR (SNP) | VAF 76/150 reads (51%) | called by muse, mutect2, varscan2
- CALN1 | c.*3105C>T | 3'UTR (SNP) | VAF 47/99 reads (47%) | called by muse, mutect2, varscan2
- CCNH | chr5:87393902 G>T | 3'Flank (SNP) | VAF 19/56 reads (34%) | catalogued as rs998291463; called by muse, mutect2, varscan2
- CDH19 | c.*3714A>T | 3'UTR (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- CDH8 | c.*1280A>C | 3'UTR (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- CSRNP3 | c.*6471C>A | 3'UTR (SNP) | VAF 37/73 reads (51%) | called by muse, mutect2, varscan2
- DGKB | c.*428C>T | 3'UTR (SNP) | VAF 72/149 reads (48%) | catalogued as rs895579680; called by muse, mutect2, varscan2
- EXT1 | c.*5059A>G | 3'UTR (SNP) | VAF 73/138 reads (53%) | catalogued as rs1055994330; called by muse, mutect2, varscan2
- FBXL20 | c.1203+99A>T | Intron (SNP) | VAF 7/11 reads (64%) | called by muse, varscan2
- GLYATL1 | n.14G>A | RNA (SNP) | VAF 27/59 reads (46%) | catalogued as rs967720320; called by muse, mutect2, varscan2
- HTR3B | c.-176C>G | 5'UTR (SNP) | VAF 46/96 reads (48%) | called by muse, mutect2, varscan2
- INVS | c.273+3978G>A | Intron (SNP) | VAF 54/112 reads (48%) | called by muse, mutect2, varscan2
- KAT6A | c.1483-1994G>A | Intron (SNP) | VAF 46/94 reads (49%) | called by muse, mutect2, varscan2
- MED12L | chr3:151086614 G>A | 5'Flank (SNP) | VAF 64/128 reads (50%) | catalogued as rs1424858868; called by muse, mutect2, varscan2
- MICAL3 | c.2801+544T>C | Intron (SNP) | VAF 48/111 reads (43%) | called by muse, varscan2
- MICAL3 | c.2801+543C>G | Intron (SNP) | VAF 46/106 reads (43%) | called by muse, varscan2
- MIP | c.*1659A>G | 3'UTR (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- MOB3C | c.-51+645G>A | Intron (SNP) | VAF 42/88 reads (48%) | called by muse, varscan2
- MRGPRX10P | n.179G>A | RNA (SNP) | VAF 52/98 reads (53%) | called by muse, mutect2, varscan2
- NPNT | c.172+14151A>T | Intron (SNP) | VAF 88/176 reads (50%) | called by muse, mutect2, varscan2
- PLXNA4 | c.*4162C>T | 3'UTR (SNP) | VAF 40/87 reads (46%) | catalogued as rs550644009; called by muse, mutect2, varscan2
- PRPF8 | c.-11-94G>A | Intron (SNP) | VAF 19/38 reads (50%) | called by muse, mutect2, varscan2
- PRSS38 | c.*220T>C | 3'UTR (SNP) | VAF 45/95 reads (47%) | called by muse, mutect2, varscan2
- PTGS1 | c.*837G>A | 3'UTR (SNP) | VAF 36/72 reads (50%) | called by muse, varscan2
- RAB26 | c.*648G>C | 3'UTR (SNP) | VAF 41/90 reads (46%) | called by muse, mutect2, varscan2
- RAB32 | c.*179C>A | 3'UTR (SNP) | VAF 57/115 reads (50%) | called by muse, varscan2
- RICTOR | c.4136+285G>T | Intron (SNP) | VAF 79/169 reads (47%) | catalogued as COSV99705792; called by muse, mutect2, varscan2
- RPL38 | c.64+162T>G | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- RTN2 | c.34+192C>G | Intron (SNP) | VAF 30/50 reads (60%) | called by muse, mutect2, varscan2
- SENP7 | c.1837+486T>C | Intron (SNP) | VAF 16/48 reads (33%) | called by muse, mutect2, varscan2
- SEPTIN4 | c.1607-134G>C | Intron (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- SNORD116-11 | chr15:25079221 G>A | 3'Flank (SNP) | VAF 72/137 reads (53%) | called by muse, mutect2, varscan2
- ST6GALNAC3 | c.*5771A>C | 3'UTR (SNP) | VAF 37/76 reads (49%) | called by muse, mutect2, varscan2
- TSC1 | c.*1251C>T | 3'UTR (SNP) | VAF 65/161 reads (40%) | catalogued as rs773490178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WASF2 | c.*2201C>G | 3'UTR (SNP) | VAF 86/164 reads (52%) | called by muse, mutect2, varscan2
- ZDHHC17 | c.*206G>A | 3'UTR (SNP) | VAF 59/125 reads (47%) | catalogued as COSV100602354; called by muse, mutect2, varscan2
